Surgical pathology report (de-identified scan), TCGA case TCGA-77-7338, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7338-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Anatomical Pathology (HIST) Spec:
RIGHT UPPER LOBECTOMY AND MEDIASTINAL LYMPH NODE BIOPSIES

Clinical Details:
SCC lung.

Five specimens received:

A: RIGHT UPPER LOBE

Macroscopy:

The specimen is labelled "right upper lobe" and consists of a lobe of lung measuring 130 x 120 x 40 mm. Within 10 mm of the endobronchial resection margin, a solid well circumscribed pale tumour measuring 35 mm in maximum dimension is seen. There are areas of central necrosis within the tumour. [Bronchial resection margin A1, R.S. of tumour A2-A7. Note: Blocks A3 and A4 contain lateral pleura, Blocks A6 and A7 contain mediastinal pleura and soft tissue. R.S. of main involved lung A8.

Microscopy:

Sections show a moderately-differentiated squamous cell carcinoma which shows involvement of the peribronchial resection margin, predominantly through spread along perineural spaces. The carcinoma does not involve overlying pleura. The remaining lung parenchyma shows changes of emphysema, predominantly in a subpleural location.

B: 7 NODE

[page 2 of 3]
Anatomical Pathology Continued

Macroscopy:

The specimen is labelled "7 Node" and consists of several fragments of pigmented lymph nodes. [Blocked in toto, B1-B2].

Microscopy:

The lymph nodes show reactive changes only: there is no evidence of metastatic carcinoma.

C: 11 R NODE

Macroscopy:

The specimen is labelled "11 R Node" and consists of a single fragment of pigmented lymph node. [Blocked in toto, C1].

Microscopy:

The lymph node shows minor reactive changes only: there is no evidence of metastatic carcinoma.

D: 4 R NODE

Macroscopy:

The specimen is labelled "4 R Node" and consists of a single fragment of pigmented lymph node. [Blocked in toto, D1].

Microscopy:

The lymph node shows minor reactive changes only: there is no evidence of metastatic carcinoma.

E: HILAR NODE

Macroscopy:

The specimen is labelled "hilar node" and consists of two fragments of pigmented nodal tissue. [Blocked in toto, E1].

[page 3 of 3]
Anatomical Pathology Continued

Final

Microscopy:

The lymph nodes show reactive changes only: there is no evidence of metastatic carcinoma.

cc: [REDACTED]

Pathologist: [REDACTED]

Validated by [REDACTED]

Source: NCI Genomic Data Commons file 31ca6020-f043-47db-a5c9-423b487f9e38 (TCGA-77-7338.BE1035B5-A744-4574-ADD2-31D2AB9CCDC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).